Somatic mutation profile of tumor specimen TCGA-61-1915-01A (aliquot TCGA-61-1915-01A-01W-0639-09) from TCGA case TCGA-61-1915, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 50.4 years (18,424 days).
Specimen TCGA-61-1915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de2ef038-a53c-4641-9108-a3229125afb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1915-11A (Solid Tissue Normal), aliquot TCGA-61-1915-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c8806da-0416-4c3a-95fa-7e4d2125fee0

The open-access MAF lists 103 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 25, Nonsense Mutation 4, Splice Region 3, Frame Shift Del 3, Splice Site 3, In Frame Del 2, 3'UTR 2, 5'Flank 2, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 58/86 reads (67%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.856T>G p.C286G | Missense Mutation (SNP) | VAF 335/1116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419111; called by muse, mutect2, varscan2
- ADCK2 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV99301935; called by muse, mutect2
- ADCY6 | c.2459T>C p.M820T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57166847; called by muse, mutect2, varscan2
- ANKRD30A | c.1427A>T p.E476V (on ENST00000611781; = p.E420V on NM_052997.2) | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV64607273; called by muse, mutect2, varscan2
- AP1G2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV58111258; called by muse, mutect2, varscan2
- AQR | c.1229G>C p.R410P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV50031097; called by muse, mutect2, varscan2
- ASNSD1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV53623248, COSV99641470; called by muse, mutect2, varscan2
- B3GALNT1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV57579986; called by muse, mutect2, varscan2
- B4GALT5 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 264/528 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs916716942, COSV65492717; called by muse, mutect2, varscan2
- BBS2 | c.1908C>T p.D636= | Splice Region (SNP) | VAF 107/622 reads (17%) | catalogued as rs1179270658, COSV55325704; called by muse, mutect2, varscan2
- BSN | c.4229C>G p.P1410R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as rs1190442902, COSV56515170; called by muse, mutect2, varscan2
- CALB2 | c.171+2T>A p.X57_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | catalogued as COSV56938688; called by muse, mutect2, varscan2
- CHRNB2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.301); catalogued as rs760653937, COSV63807926; called by muse, mutect2, varscan2
- CPAMD8 | c.2211+1G>A p.X737_splice (on ENST00000651564; = p.X690_splice on NM_015692.5) | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as rs374939930; called by muse, mutect2
- CREB3L2 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV57793622; called by muse, mutect2, varscan2
- CSMD2 | c.9360G>C p.Q3120H | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV99596665; called by muse, mutect2
- CTNNA3 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs746246837, COSV65565917; called by muse, mutect2, varscan2
- DCLK3 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs368283858; called by muse, mutect2, varscan2
- DENND4C | c.3275G>C p.R1092T (on ENST00000434457 / NM_001330640.2; = p.R1043T on NM_017925.7) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63008558; called by muse, mutect2, varscan2
- DHX29 | c.1761G>C p.R587S | Missense Mutation (SNP) | VAF 137/530 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52417497; called by muse, varscan2
- EFEMP1 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 88/140 reads (63%) | catalogued as COSV62615519; called by muse, mutect2, varscan2
- FRMPD3 | c.2624T>C p.L875P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52188476; called by muse, mutect2, varscan2
- HECTD3 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV64669864, COSV64670377; called by muse, mutect2, varscan2
- IGSF22 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV60032252; called by muse, mutect2, varscan2
- IQUB | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs180949404, COSV61238047; called by muse, mutect2, varscan2
- ITGA2 | c.2620G>C p.V874L | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV56858075; called by muse, mutect2, varscan2
- KLRK1 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV53698227, COSV53699657; called by muse, mutect2
- LIPI | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60709758; called by muse, mutect2, varscan2
- LRCH1 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 175/233 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60845711; called by muse, mutect2, varscan2
- LTBP3 | c.2375G>C p.G792A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.484); catalogued as COSV54211417; called by muse, mutect2, varscan2
- LZTS1 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV56116315; called by muse, mutect2, varscan2
- MCC | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56726789; called by muse, mutect2, varscan2
- MEST | c.506C>G p.T169S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.098); catalogued as COSV56227863; called by muse, mutect2, varscan2
- MMP13 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV52823440; called by muse, mutect2, varscan2
- NCKAP1L | c.306G>T p.R102= | Splice Region (SNP) | VAF 33/221 reads (15%) | catalogued as COSV53205054; called by muse, mutect2, varscan2
- NHLH1 | c.321dup p.D108Rfs*8 | Frame Shift Ins (INS) | VAF 4/15 reads (27%) | catalogued as rs760805876; called by mutect2, varscan2
- NOTCH4 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1249487271, COSV66679715; called by muse, mutect2, varscan2
- NPR2 | c.1589C>G p.A530G | Missense Mutation (SNP) | VAF 109/144 reads (76%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV61309926; called by muse, mutect2, varscan2
- NRG3 | c.2081T>G p.L694R (on ENST00000404547 / NM_001370084.1; = p.L670R on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV100932712, COSV64562243; called by muse, mutect2
- NUP210 | c.1841C>G p.A614G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs766934796, COSV54404435; called by muse, mutect2, varscan2
- PAK3 | c.8A>C p.D3A | Missense Mutation (SNP) | VAF 39/510 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV99458539; called by muse, mutect2
- PAXIP1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68185362; called by muse, mutect2, varscan2
- PCGF3 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62858763; called by muse, mutect2
- PEDS1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59011151; called by muse, mutect2, varscan2
- PRSS21 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.082); catalogued as COSV99135773; called by muse, mutect2, varscan2
- PSMF1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs757987133, COSV55673443; called by muse, mutect2, varscan2
- PYGB | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99405546; called by muse, mutect2, varscan2
- RCN2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58031223; called by muse, mutect2, varscan2
- RICTOR | c.390T>C p.A130= | Splice Region (SNP) | VAF 115/415 reads (28%) | catalogued as COSV57119513; called by muse, mutect2, varscan2
- RIN2 | c.1120C>G p.L374V (on ENST00000255006 / NM_001242581.1; = p.L325V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as COSV54786093; called by muse, mutect2, varscan2
- SAP130 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen probably damaging (0.935); catalogued as COSV52095636; called by muse, mutect2, varscan2
- SATL1 | c.889C>T p.P297S (on ENST00000395409; = p.P484S on NM_001012980.2) | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60576006; called by muse, mutect2, varscan2
- SDCBP2 | c.450C>G p.D150E (on ENST00000339987 / NM_001199784.1; = p.D65E on NM_015685.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60588769; called by muse, mutect2, varscan2
- SLC22A2 | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV65265925; called by muse, mutect2, varscan2
- SPPL2A | c.585-1G>A p.X195_splice | Splice Site (SNP) | VAF 17/108 reads (16%) | catalogued as COSV55940484; called by muse, mutect2, varscan2
- STX5 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV53678655; called by muse, mutect2, varscan2
- SYNGAP1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53379664; called by muse, varscan2
- SYT11 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.113); catalogued as rs371162872; called by muse, mutect2, varscan2
- TAF6 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1231373242, COSV100612895; called by muse, mutect2
- TBC1D22B | c.199del p.S67Vfs*22 | Frame Shift Del (DEL) | VAF 71/470 reads (15%) | catalogued as COSV65142529; called by mutect2, pindel, varscan2
- TLCD3B | c.506C>G p.T169R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54226547; called by muse, mutect2, varscan2
- TNFRSF11A | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54022576; called by muse, mutect2, varscan2
- TNFRSF8 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.138); catalogued as COSV55795494; called by muse, mutect2, varscan2
- TTN | c.60452A>C p.Y20151S (on ENST00000591111; = p.Y12727S on NM_003319.4) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | PolyPhen probably damaging (0.998); catalogued as COSV59961501; called by muse, mutect2, varscan2
- VWA3B | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.057); catalogued as COSV68241899; called by muse, mutect2, varscan2
- ZMYM4 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 118/544 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as COSV58908512; called by muse, mutect2, varscan2
- ZNF337 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV53320778; called by muse, mutect2, varscan2
- FSCN3 | c.990del p.H331Tfs*36 | Frame Shift Del (DEL) | VAF 103/319 reads (32%) | called by mutect2, pindel, varscan2
- MICAL2 | c.3962_3976del p.S1321_P1325del | In Frame Del (DEL) | VAF 26/238 reads (11%) | called by mutect2, pindel
- MRTFB | c.1734_1735del p.K579Afs*24 | Frame Shift Del (DEL) | VAF 38/223 reads (17%) | called by pindel, varscan2
- ZNF687 | c.715_726del p.S239_S242del | In Frame Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- ARL3 | c.60A>C p.I20= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as COSV53299265; called by muse, mutect2, varscan2
- ATP6V0D2 | c.15G>A p.A5= | Silent (SNP) | VAF 56/316 reads (18%) | catalogued as rs201771660, COSV53413867; called by muse, mutect2, varscan2
- CLN3 | c.237G>A p.A79= (on ENST00000360019 / NM_001286104.2; = p.A103= on NM_000086.2) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs774996613, COSV100343521, COSV61105391; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNGB1 | c.3426G>A p.L1142= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs540706326, COSV51899154; called by muse, mutect2, varscan2
- CYSLTR1 | c.924A>G p.T308= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV64819737; called by muse, mutect2, varscan2
- EXOC8 | c.1623C>T p.F541= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs963842863, COSV50477860; called by muse, mutect2, varscan2
- HS3ST4 | c.967C>T p.L323= | Silent (SNP) | VAF 109/494 reads (22%) | catalogued as COSV58808300; called by muse, mutect2, varscan2
- IGF2BP3 | c.1182T>G p.T394= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV51682244; called by muse, mutect2, varscan2
- INTS5 | c.2823G>C p.L941= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs551521257, COSV57950862, COSV57953269; called by muse, mutect2, varscan2
- KANK1 | c.1548G>T p.V516= | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV63211164; called by muse, mutect2, varscan2
- LRIT2 | c.1563T>C p.F521= | Silent (SNP) | VAF 72/149 reads (48%) | catalogued as COSV60560848; called by muse, mutect2, varscan2
- MEI1 | c.2574A>C p.T858= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV55901874; called by muse, mutect2, varscan2
- PLCE1 | c.933A>G p.E311= | Silent (SNP) | VAF 94/449 reads (21%) | catalogued as COSV99597693; called by muse, mutect2
- PRSS21 | c.285G>T p.G95= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99135777; called by muse, mutect2, varscan2
- PTPN23 | c.1530C>T p.F510= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV55543636, COSV55546134; called by muse, mutect2, varscan2
- RBM27 | c.1248A>G p.L416= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54588681; called by muse, mutect2, varscan2
- SLC6A6 | c.810G>A p.A270= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs768739430, COSV62648445; called by muse, varscan2
- SLX4 | c.396A>G p.E132= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV53562528; called by muse, mutect2, varscan2
- SNRNP40 | c.336G>A p.V112= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV55276874; called by muse, mutect2, varscan2
- SPG11 | c.5724C>T p.V1908= | Silent (SNP) | VAF 61/291 reads (21%) | catalogued as rs369869911, COSV55991996; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYMPK | c.1530C>A p.S510= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99842248; called by muse, mutect2
- TLR4 | c.2355G>C p.L785= (on ENST00000355622 / NM_138554.5; = p.L745= on NM_003266.4) | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV62922786; called by muse, mutect2, varscan2
- USH2A | c.2733C>A p.T911= | Silent (SNP) | VAF 103/463 reads (22%) | catalogued as COSV56348189; called by muse, mutect2, varscan2
- ZBED9 | c.3112T>C p.L1038= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as COSV71729261; called by muse, mutect2, varscan2
- ZMYM2 | c.762T>C p.T254= | Silent (SNP) | VAF 92/252 reads (37%) | catalogued as COSV67033149; called by muse, mutect2, varscan2
- AL441992.2 | c.*1C>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100223910; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502184 C>G | 5'Flank (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- DSCR4 | n.361G>A | RNA (SNP) | VAF 478/589 reads (81%) | catalogued as COSV60299742; called by muse, mutect2, varscan2
- FAM126B | c.*1T>A | 3'UTR (SNP) | VAF 140/234 reads (60%) | catalogued as rs748345663, COSV99628341; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172427 G>A | 5'Flank (SNP) | VAF 7/35 reads (20%) | catalogued as COSV68841165; called by muse, mutect2, varscan2
- ZNF618 | c.755-547G>C | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55918908; called by muse, mutect2, varscan2
